Somatic mutation profile of tumor specimen TCGA-2G-AAM2-01A (aliquot TCGA-2G-AAM2-01A-11D-A435-10) from TCGA case TCGA-2G-AAM2, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AAM2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56fd3ff2-4235-4690-b5b1-00f3d0205bab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAM2-10A (Blood Derived Normal), aliquot TCGA-2G-AAM2-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/105fb714-c88d-4f01-8815-ec6c6f1a4d9b

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCKR | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs761890302, COSV53107786, COSV53109497; called by muse, mutect2, varscan2
- LMO3 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.302); catalogued as COSV99662538; called by muse, mutect2
- RAD54L2 | c.3399G>A p.M1133I | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs770073578; called by muse, mutect2, varscan2
- DDX59 | c.1345G>C p.V449L | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- IRS2 | c.2469C>A p.Y823* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2
- OTUD1 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PKHD1 | c.9620C>T p.A3207V | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VWA2 | c.2191A>G p.N731D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- ZNF398 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANAPC5 | c.714G>A p.K238= | Silent (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- ARMC2 | c.1911G>A p.T637= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs552011948; called by muse, varscan2
- FLT4 | c.1386C>A p.P462= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- KRT72 | c.921C>A p.A307= | Silent (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- MAPK1IP1L | c.57C>T p.T19= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs1344302735, COSV101133319; called by muse, mutect2, varscan2
